Surgical pathology report (de-identified scan), TCGA case TCGA-K4-A3WS, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K4-A3WS-01A (Primary Tumor).

[page 1 of 6]
Name

Encounter Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

ICD-O-3

carcinoma, urothelial, NOS
8120/3

Final

Site: bladder, NOS

C67.9 5112
RD

Source of Specimen

- A. LEFT DISTAL URETER FS-
- B. RIGHT DISTAL URETER FS-
- C. LEFT PELVIC LYMPH NODES-
- D. RIGHT PELVIC LYMPH NODES-
- E. BLADDER, PROSTATE, SEMINAL VESICLES AND VAS DEFERENS-

FINAL DIAGNOSIS:

- A. LEFT DISTAL URETER FS-
SEGMENT OF URETER WITH NO TUMOR SEEN.
- B. RIGHT DISTAL URETER FS-
SEGMENT OF URETER WITH NO TUMOR SEEN.
- C. LEFT PELVIC LYMPH NODES-
THREE LYMPH NODE WITH NO TUMOR SEEN (0/3).
- D. RIGHT PELVIC LYMPH NODES-
TWO LYMPH NODE WITH NO TUMOR SEEN (0/2).
- E. BLADDER, PROSTATE, SEMINAL VESICLES AND VAS DEFERENS-
TRANSITIONAL CELL CARCINOMA OF URINARY BLADDER (see synoptic
report #1 below).
ADENOCARCINOMA OF PROSTATE (see synoptic report #2 below).
ONE PERICYSTIC LYMPH NODE WITH NO TUMOR SEEN

SYNOPTIC REPORT #1:

INVASIVE CARCINOMA, HIGH GRADE

TUMOR SITE: LEFT LATERAL, POSTERIOR, TRIGONE AREAS OF URINARY
BLADDER

Prepar

MRSA Discrepancy		/

[page 2 of 6]
HISTOLOGIC TYPE: UROTHELIAL

SQUAMOUS DIFFERENTIATION: NOT FOUND

GLANDULAR DIFFERENTIATION: NOT FOUND

TUMOR SIZE: GROSSLY 2 CM MASS

HISTOLOGIC GRADE: 2-3/3

EXTRAVESICULAR MASS: FOCAL MICROSCOPICALLY PRESENT

SPECIMEN TYPE: RADICAL CYSTOPROSTATECTOMY

TNM STAGE: pT3a, pN0, pMX.

(T3a: microscopically; T3b, macroscopically)

(N1, single pelvic node; N2, multiple pelvic nodes; N3, common iliac node)

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 6

LYMPHATIC (SMALL VESSEL) INVASION: FOCALLY SUSPECTED

ASSOCIATED EPITHELIAL LESIONS: PATCHY AREAS OF TRANSITIONAL
CELL CARCINOMA IN SITU IDENTIFIED

NO TUMOR SEEN AT SPECIMEN MARGINS

SYNOPSIS REPORT #2:

ADENOCARCINOMA OF PROSTATE

NO EXTRAPROSTATIC EXTENSION SEEN

TUMOR SITE: BILATERAL

SPECIMEN TYPE: RADICAL CYSTOPROSTATECTOMY

SIZE: 4 x 3.5 x 3.5 CM

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 4 = 7/10

SEVERITY IN EXTENT OF TUMOR: 3 /5

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue
involvement)

[page 3 of 6]
TNM STAGE: pT2c, pN0, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: NOT FOUND

PERINEURAL INVASION: NOT FOUND

NO TUMOR SEEN IN SEMINAL VESICLES

NO TUMOR SEEN AT SPECIMEN MARGINS

(

Signed Others

Frozen Section

A. LEFT DISTAL URETER- NO TUMOR SEEN.

RIGHT DISTAL URETER- NO TUMOR SEEN.

Case Clinical Information

BLADDER CANCER

Gross Description

- A. Received in formalin labeled with the patient's name and "left distal ureter-FS" is a 0.4 cm frozen section tissue remnant. Wrapped and entirely submitted in A1.
- B. Received in formalin labeled with the patient's name and "right distal ureter-FS" is a 0.4 cm frozen section tissue remnant. Wrapped and entirely submitted in B1.
- C. Received in formalin labeled with the patient's name and "left pelvic lymph nodes" are three nodules of tan fatty tissue grossly consistent with lymphoid tissue. The specimens range in size from 2 cm down to 1 cm. The excess fat is trimmed. All nodes are submitted as follows: C1= one lymph node, bisected; C2-C3= one lymph node each.
- D. Received in formalin labeled with the patient's name and "right pelvic lymph nodes" are three nodular fragments of tan fatty tissue consistent with lymphoid tissue ranging in size from 2 cm down to 0.8 cm. The excess fat is trimmed and all
-

[page 4 of 6]
three possible nodes are submitted as follows: D1= one lymph node that has been bisected; D2-D3= one lymph node each.

E. Received in formalin labeled with the patient's name and "bladder, prostate, seminal vesicles and vas deferens" is a radical cystectomy specimen with attached prostate and attached associated fat. Overall dimensions of the specimen measure 16 x 9 x 5 cm thick. The attached prostate measures 4 x 3.5 x 3.5 cm and has a shaggy capsule. The left and right ureters are embedded in the fat and these margins have been previously taken for frozen section evaluation. The left seminal vesicle measures 3 x 1 x 1 cm. The left vas deferens measures 6 cm in length. The right seminal vesicle measures 3.5 x 1 x 1 cm. The right vas deferens measures 7 cm in length. The bladder is opened anteriorly and in the left posterolateral aspect, the bladder mucosa reveals a tan/brown ulcerated lesion measuring 2 x 1.5 x 0.5 cm. The remainder of the bladder mucosa has a tan edematous/retracted appearance. No additional lesions are identified. The cut surface of the mass has a smooth tan/pink indurated appearance. Grossly, this appears to have invaded into the muscularis. The remainder of the right lateral wall has a fibrous appearance and is unremarkable. The right lateral wall is sectioned to reveal an unremarkable tan/pink tissue. The cut surface of the prostate has a firm, focally nodular parenchyma and is grossly unremarkable. Representative sections of the specimen are submitted as follows: E1-E2= prostatic urethral margin, left and right sides respectively; E3-E4= full thickness cross sections demonstrating mass left posterior wall; E5-E8= full thickness cross sections of mass left lateral wall; E9= left trigone; E10= right trigone; E11-E12= right posterior wall; E13-E14= right lateral wall; E15= right dome; E16= left dome; E17-E21= representative sections of upper, mid and lower prostate left side; E22-E24= representative full thickness sections of upper, mid and lower prostate 1/3 of prostate right side; E25= representative section of bladder tumor for research; E26= representative section of normal bladder for research; E27= representative section of tumor, prostate, for research; E28= representative section of normal tissue, prostate, for research.

Pt

I

Procedure

A. AA ROUTINE H&E X1 BLOCK

H&E X1

B. AA ROUTINE H&E X1 BLOCK

H&E X1

C. AA ROUTINE H&E X1 BLOCK.1

H&E X1

Prepared for

M

[page 5 of 6]
C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
C. AA ROUTINE H&E X1 BLOCK.3
H&E X1
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
D. AA ROUTINE H&E X1 BLOCK.3
H&E X1
E. AA ROUTINE H&E X1 BLOCK.1
H&E X1
E. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK.3
H&E X1
E. AA ROUTINE H&E X1 BLOCK.4
H&E X1
E. AA ROUTINE H&E X1 BLOCK.5
H&E X1 AA RECUT
E. AA ROUTINE H&E X1 BLOCK.6
H&E X1
E. AA ROUTINE H&E X1 BLOCK.7
H&E X1 AA RECUT
E. AA ROUTINE H&E X1 BLOCK.8
GOOD COMPLETE SECTIONS
H&E X1 AA RECUT
E. AA ROUTINE H&E X1 BLOCK.9
H&E X1
E. AA ROUTINE H&E X1 BLOCK.10
H&E X1
E. AA ROUTINE H&E X1 BLOCK.11
H&E X1
E. AA ROUTINE H&E X1 BLOCK.12
H&E X1
E. AA ROUTINE H&E X1 BLOCK.13
H&E X1
F. AA ROUTINE H&E X1 BLOCK.14
H&E X1
F. AA ROUTINE H&E X1 BLOCK.15
H&E X1
E. AA ROUTINE H&E X1 BLOCK.16
H&E X1
E. AA ROUTINE H&E X1 BLOCK.17
H&E X1
E. AA ROUTINE H&E X1 BLOCK.18
H&E X1
E. AA ROUTINE H&E X1 BLOCK.19

[page 6 of 6]
H&E X1
E. AA ROUTINE H&E X1 BLOCK.20
H&E X1
E. AA ROUTINE H&E X1 BLOCK.21
H&E X1
E. AA ROUTINE H&E X1 BLOCK.22
H&E X1
E. AA ROUTINE H&E X1 BLOCK.23
PLEASE PLACE THE SECTION ON THE SLIDESO THAT I CAN SEE ALL OF IT
...
H&E X1 AA RECUT
E. AA ROUTINE H&E X1 BLOCK.24
H&E X1
E. AA ROUTINE H&E X1 BLOCK.25
H&E X1
E. AA ROUTINE H&E X1 BLOCK.26
H&E X1
E. AA ROUTINE H&E X1 BLOCK.27
H&E X1
E. AA ROUTINE H&E X1 BLOCK.28
H&E X1

Prepare

Source: NCI Genomic Data Commons file 846840c9-f84c-4edd-bac3-44c650e4f150 (TCGA-K4-A3WS.57743D2E-0677-40AD-A1EE-430EFF8F3F2A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).